Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3436, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3436-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left renal mass.

Source of Specimen(s):

A: left kidney and adrenals

B: peri aortic lymph nodes

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled # 1, "Left kidney".

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "left kidney". It consists of a left nephrectomy specimen with attached perinephric fat having an overall measurement of 20 x 12 x 9 cm. The specimen weighs 700 gm and the adrenal gland is identified measuring 3 x 3 x 1.5 cm. The adrenal gland is yellowish-orange and normal appearing. The inferior pole of the kidney is bulging. At the hilum, there is an 8 cm segment of normal appearing ureter. The specimen is bivalved. The vessels are normal appearing. The kidney itself measures approximately 15 x 7 x 6.5 cm and the fat is difficult to remove. Dissection through the fat discloses no suspicious lesions, masses, or lymph nodes. In the lower pole of the kidney there is a yellowish-orange lobulated mass measuring 9 x 6 x 6 cm. The mass comprises approximately 55% of the kidney and is bulging into the renal pelvis. The tumor also bulges on the capsule, however, no gross invasion is identified. The tumor has an appreciable amount of calcifications and obliterates the inferior calix and distorts the central calix and renal pelvis.

Designation of Sections: 1A vascular ureter margin, 1B tumor and hilum, 1C-1D tumor in relationship to capsule (1C is towards renal hilum), 1E tumor, 1F normal uninvolved kidney, 1G adrenal gland, 1H-1I perinephric fat.

Summary of Sections: Representative sections are submitted in 1A-1I.

Source of Tissue: 2. Labeled # 2, "Periaortic lymph nodes".

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "periaortic lymph nodes". It consists of a few tan rubbery lymph nodes, ranging from 0.5 up to 3 cm. 2A-2C contains multiple single lymph nodes, 2D contains a single bisected lymph node, and 2E contains a single bisected lymph node.

[page 2 of 2]
Submitted entirely in 2A-2E.

Final Diagnosis:

1. Left kidney and adrenal gland, radical nephrectomy:

- Conventional (clear cell) renal carcinoma, Fuhrman grade II (9 cm) confined to the kidney.
- No angiolymphatic invasion present.
- Vascular, ureter and circumferential margins negative for tumor.
- Adrenal gland negative for tumor.
- Perinephric fat with ectopic adrenal gland.

2. Periaortic lymph node, excision:

- Twenty-two lymph nodes negative for tumor (0/22)✓

Stage: pT2,N0,Mx.

Source: NCI Genomic Data Commons file f787b086-b7bb-4029-b515-b1af1bc1f50d (TCGA-AK-3436.65A48B19-0BAC-404F-8929-C2E73424A4D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).